Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A6K2, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A6K2-01A (Primary Tumor).

[page 1 of 4]
M

(172.0cm 51.0kg BSA: 1.56m²)

Accession:

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) NECK, LEVEL IA, NECK DISSECTION:
Eight lymph nodes, negative for tumor (0/8).
- (B) RIGHT SUBMANDIBULAR GANGLION:
Fibrovascular tissue with thermal artifact.
DETACHED FRAGMENT OF ATYPICAL CELLS SUSPICIOUS FOR CARCINOMA.
- (C) RIGHT NECK DISSECTION, LEVEL IB:
Three lymph nodes, negative for tumor (0/3).
Unremarkable submandibular gland.
- (D) RIGHT EXTERNAL JUGULAR LYMPH NODE:
Six lymph nodes, negative for tumor (0/6).
- (E) RIGHT LINGUAL NERVE AT SUBMANDIBULAR GANGLION:
Nerve and ganglion cells, negative for tumor.
- (F) RIGHT NECK DISSECTION, LEVEL IIA:
Fifteen lymph nodes, negative for tumor (0/15).
- (G) RIGHT NECK DISSECTION, LEVEL III:
Nine lymph nodes, negative for tumor (0/9).
- (H) RIGHT NECK DISSECTION, LEVEL IV:
Three lymph nodes, negative for tumor (0/3).
- (I) RIGHT NECK DISSECTION, LEVEL IIB:
Five lymph nodes, negative for tumor (0/5).
- (J) RIGHT MENTAL NERVE:
Nerve tissue, negative for tumor.
- (K) TEETH, GROSS ID:
Teeth for gross evaluation only.
- (L) PROXIMAL MANDIBULAR NERVE:
Nerve, tissue, negative for tumor.
- (M) RIGHT MANDIBLE:
INVASIVE SQUAMOUS CARCINOMA WELL DIFFERENTIATED INFILTRATING INTO SKELETAL MUSCLE
- Tumor Features:
Gross: Ulcerating
Size: 4.5 cm in largest dimension
Invasion: Present, depth 1.4 cm
Tumor Border: Infiltrative with thin cords < 4 cells
Perineural Invasion: Absent
Vascular Invasion: Absent
Bone / Cartilage Invasion: cortical bone invasion present
Lymphocyte Infiltration: Absent
- (N) RIGHT BUCCAL MARGIN:
Buccal mucosa, negative for tumor.
- (O) RIGHT FLOOR OF MOUTH MARGIN:
Buccal mucosa, negative for tumor.
- (P) RIGHT RETROMOLAR MARGIN:
Mucosa with submucosal glands, negative for tumor.

ICD-O-3
Carcinoma, squamous cell
NOS
Site Oral cavity
8670/3
8/9/13

[page 2 of 4]
Accession:
Specimen Date/Time:

GROSS DESCRIPTION

- (A) NECK, LEVEL 1A, NECK DISSECTION – One pale-gray fibroadipose tissue (4.0 x 2.2 x 1.4 cm) with multiple possible lymph nodes, (ranging from 0.3 x 0.2 x 0.2 cm to 0.9 x 0.5 x 0.4 cm). The lymph nodes are entirely submitted.
SECTION CODE: A1, A2, each containing four possible lymph nodes; A3, three possible lymph nodes.
- (B) RIGHT SUBMANDIBULAR GANGLION – A 0.5 x 0.4 x 0.3 cm unoriented pink soft tissue fragment.
SECTION CODE: B, entire specimen submitted for frozen section diagnosis.
*FS/DX: 1. FIBROVASCULAR TISSUE WITH THERMAL ARTIFACT. 2. DETACHED FRAGMENT OF ATYPICAL CELLS SUSPICIOUS FOR CARCINOMA.
- (C) RIGHT NECK DISSECTION, LEVEL 1B – One pale-gray fibroadipose tissue (6.5 x 4.0 x 1.7 cm) including a pale-gray unremarkable submandibular gland (2.5 x 2.5 x 1.3 cm). Multiple lymph nodes are identified (ranging from 0.6 x 0.4 x 0.4 cm to 1.0 x 1.0 x 0.8 cm). The lymph nodes are entirely submitted.
SECTION CODE: C1, C2, each containing two possible lymph nodes; C3, one possible lymph node, serially sectioned; C4, representative section of the submandibular gland.
- (D) RIGHT EXTERNAL JUGULAR LYMPH NODE – One pale-gray fibroadipose tissue (1.7 x 0.7 x 0.6 cm) with two possible lymph nodes (0.4 x 0.2 x 0.2 cm and 0.6 x 0.5 x 0.5 cm). The lymph nodes are entirely submitted.
SECTION CODE: D1, two possible lymph nodes; D2, entirely submitted of the remainder of the fibrous tissue.
- (E) RIGHT LINGUAL NERVE AT SUBMANDIBULAR GANGLION – A 0.3 x 0.2 x 0.1 cm unoriented, pink, soft, nerve tissue fragment.
SECTION CODE: E, entire specimen submitted for frozen section diagnosis.
*FS/DX: PERIPHERAL NERVE AND GANGLION, NO TUMOR PRESENT.
- (F) RIGHT NECK DISSECTION, LEVEL 2A – One pale-gray fibroadipose tissue (5.5 x 4.0 x 1.7 cm) with multiple possible lymph nodes (ranging from 0.3 x 0.3 x 0.3 cm to 1.2 x 0.7 x 0.5 cm). The lymph nodes are entirely submitted.
SECTION CODE: F1-F3, each containing four possible lymph nodes; F4, F5, each containing two possible lymph nodes.
- (G) RIGHT NECK DISSECTION, LEVEL 3 – One pale-gray fibroadipose tissue (3.0 x 2.0 x 2.0 cm) with multiple possible lymph nodes (ranging from 0.4 x 0.3 x 0.3 cm to 0.6 x 0.6 x 0.5 cm). The lymph nodes are entirely submitted.
SECTION CODE: G1, four possible lymph nodes; G2, three possible lymph nodes; G3, two possible lymph nodes.
- (H) RIGHT NECK DISSECTION, LEVEL 4 – One pale-yellow fibroadipose tissue (2.5 x 2.0 x 1.5 cm) with three possible lymph nodes (ranging from 0.3 x 0.3 x 0.3 cm to 0.6 x 0.5 x 0.4 cm). Lymph nodes are entirely submitted.
SECTION CODE: H, three possible lymph nodes.
- (I) RIGHT NECK DISSECTION, LEVEL 2B – One pale-gray fibroadipose tissue (3.0 x 2.8 x 1.6 cm) with six possible lymph nodes (ranging from 0.2 x 0.1 x 0.1 cm to 1.2 x 0.7 x 0.6 cm). The lymph nodes are entirely submitted.
SECTION CODE: I1, three possible lymph nodes; I2, two possible lymph nodes; I3, one possible lymph node.
- (J) RIGHT MENTAL NERVE – Received tan-pink, lobulated, irregular shaped tissue (0.6 x 0.1 x 0.1 cm). The specimen is entirely embedded in one block for frozen section analysis.
*FS/DX: PERIPHERAL NERVE WITH FOCAL DISTORTION, NO TUMOR IDENTIFIED.
- (K) TEETH, GROSS ID – Multiple teeth (4.5 x 3.0 x 1.8 cm in aggregate). Teeth for gross evaluation only.
- (L) PROXIMAL MANDIBULAR NERVE – Received tan-pink, irregular shaped tissue (0.6 x 0.1 x 0.1 cm). The specimen is entirely embedded in one block for frozen section analysis.
*FS/DX: PERIPHERAL NERVE, NO TUMOR PRESENT.
- (M) RIGHT MANDIBLE – Hemimandibulectomy (12 x 6 x 5 cm), mostly edentulous (two teeth present). Gingiva is entirely replaced by an ulcerated large tan, ill defined firm mass (4.5 x 4.5 x 4 cm) invading into adjacent soft tissue and cortical bone. Representative sections submitted in M1-M12 (M1-2, soft tissue edges, M3-M12 tumor and adjacent/ subjacent soft tissue).
M13, anterior bone resection margin en face for decalcification.
- (N) RIGHT BUCCAL MARGIN – One piece of pink fibromembranous tissue (3.1 x 0.3 x 0.3 cm) submitted as en face margin for frozen section analysis in N1.
*FS/DX: NO TUMOR PRESENT.
- (O) RIGHT FLOOR OF MOUTH MARGIN – One piece of pink fibromembranous tissue (3.2 x 0.3 x 0.3 cm). Specimen is submitted as en face margin for frozen section analysis in O1.
*FS/DX: NO TUMOR PRESENT.
- (P) RIGHT RETROMOLAR MARGIN – Are two pieces of pink fibromembranous tissue (2.3 x 0.2 x 0.2 cm and 0.8 x 0.2 x 0.2 cm).

[page 3 of 4]
Accession: M (172.6cm 51.0kg BSA: 1.66m²)
Specimen Date/Time:

Specimen is submitted in toto as en face margins for frozen section evaluation in P1.
*FS/DX: NO TUMOR PRESENT.

CLINICAL HISTORY

SNOMED CODES

T-11180, M-80703

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

these tests have not been

Entire report and diagnosis completed by: □

Start of ADDENDUM

[page 4 of 4]
M (172.0cm 51.0kg BSA: 1.56m²)

Accession:
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Decalcified section of anterior bone resection margin (slide M13) reveals bone and fibroconnective tissue, negative for malignancy.

Entire report and diagnosis completed by:

-----END OF REPORT-----

HPA Discrepancy		☒

Source: NCI Genomic Data Commons file 9d35d14d-86f1-4c5f-a479-1472c214a73a (TCGA-CV-A6K2.BD90BD95-8671-4D03-9443-8D35E615F68D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).